TCGA case TCGA-DK-AA76 — Bladder Urothelial Carcinoma (TCGA-BLCA)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Transitional Cell Papillomas and Carcinomas; Primary site: Bladder; Tissue source site: Memorial Sloan Kettering. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/d37b0460-efa4-4cf5-8082-f27ff2cf2f28

Demographics
Sex at birth: female; Race: white; Ethnicity: not hispanic or latino; Country of residence at enrollment: United States; Age at index: 64 years; Vital status: Alive.

Diagnoses (1)
1. Transitional cell carcinoma: ICD-O-3 morphology code: 8120/3; ICD-10 code: C67.3; Tissue or organ of origin: Anterior wall of bladder; Site of resection or biopsy: Bladder, NOS; Classification of tumor: primary; Age at diagnosis: 64.5 years (23,542 days); Year of diagnosis: 2013; Method of diagnosis: Surgical Resection; AJCC staging edition: 7th; AJCC clinical T: T2; AJCC pathologic N: N0; AJCC pathologic M: M0; AJCC pathologic stage: Stage II; Tumor grade: High Grade; Prior malignancy: no; Synchronous malignancy: No; Prior treatment: No; Days to last follow up: 366 days (1.0 years).
   Pathology details: Consistent pathology review: Yes; Lymphatic invasion present: No; Vascular invasion present: No.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Cisplatin + Gemcitabine Hydrochloride; Days to treatment start: 54 days; Days to treatment end: 114 days; Treatment outcome: Complete Response.
   Recorded as not given: adjuvant Radiation Therapy, NOS.

Follow-up (2 entries)
- Days to follow up: 366 days (1.0 years); Disease response: With Tumor.
- Karnofsky performance status: 90.

Other clinical attributes
- Timepoint category: Initial Diagnosis; Weight: 85 kg; Height: 161 cm; BMI: 32.8.

Exposures
- Chemical exposure type: Chemical Exposure, NOS; Occupation type: Client Information Workers.
- Exposure type: Tobacco; Tobacco smoking status: Current Reformed Smoker for < or = 15 yrs; Pack years smoked: 40; Tobacco smoking quit year: 2013.

Biospecimens (2 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-DK-AA76-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT; Initial weight: 380 mg.
  Slide TCGA-DK-AA76-01A-01-TSA: Section location: Top; Percent tumor cells: 100; Percent tumor nuclei: 60; Percent normal cells: 0; Percent necrosis: 0; Percent stromal cells: 0; Percent lymphocyte infiltration: 2; Percent monocyte infiltration: 0; Percent neutrophil infiltration: 0.
- Sample TCGA-DK-AA76-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Prospective collection: Yes; Retrospective collection: No; History neoadjuvant treatment: No; Tumor status: With tumor; Occupation current: Retired; Occupation primary: Reservation Agent; Occupation primary chemical exposure: Reservation Agent; Occupation primary industry: Customer Service; Tobacco smoking history indicator: 4; Histologic diagnosis: Muscle invasive urothelial carcinoma (pT2 or above); Histologic subtype: Papillary; Anatomic organ subdivision: Bladder - NOS; Method initial path diagnosis: Transurethral resection (TURBT); Lymph nodes examined: No; Lymphovascular invasion: No; Incidental prostate cancer indicator: No; Treatment outcome first course: Complete Remission/Response; New tumor event diagnosis indicator: No.
- History non muscle invasive blca: Noninvasive bladder history: No.
- Drug treatment 2: Pharmaceutical therapy drug name: Gemzar.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: no event (censored), 366 days; disease-specific survival: no event (censored), 366 days; disease-free interval: no event (censored), 366 days; progression-free interval: no event (censored), 366 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; aliquot TCGA-DK-AA76-01A-11D-A390-01): tumor purity 0.93, ploidy 1.92, whole-genome doublings 0.
